Gene-level copy-number profile of tumor specimen C3N-03490-02 from CPTAC case C3N-03490, project CPTAC-3 (Base of tongue — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Base of tongue, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 65.0 years (23,729 days).
Specimen C3N-03490-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Tongue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file dd1e2cf0-c997-4454-9fca-ed35c4dd8b91.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03490-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,960 have no estimate.
https://portal.gdc.cancer.gov/files/d1c1728d-134a-48e5-ac7c-b5ffec0558cf

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 405; copy number 1: 2,738; copy number 2: 29,603; copy number 3: 15,878; copy number 4: 6,827; copy number 5: 447; copy number 6: 1,190; copy number 7: 785; copy number 8: 104; copy number 9: 93; copy number 11: 194; copy number 12: 85; copy number 13: 156; copy number 14: 77; copy number 60: 48; copy number 80: 23; copy number 96: 4; copy number 119: 6.

Homozygous deletions (total copy number 0; autosomes only): 65 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:89,551–91,105, 1 gene (within-gene range 0–4): AL627309.3.
- chr1:25,242,249–25,338,213, 6 genes (within-gene range 0–2): RSRP1, AL031432.3, AL031432.2, RHD, SDHDP6, AL928711.1.
- chr3:130,048,143–130,055,920, 1 gene: AC083906.4.
- chr4:68,537,184–68,568,527, 1 gene (within-gene range 0–1): UGT2B17.
- chr8:1,763,888–1,958,627, 1 gene (within-gene range 0–1): AC019257.8.
- chr8:1,823,926–1,963,131, 2 genes: ARHGEF10, AC019257.9.
- chr9:10,532,145–10,532,411, 1 gene (within-gene range 0–1): AL135790.2.
- chr9:21,638,285–25,938,434, 38 genes: H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL365204.1, AL365204.2, AL365204.3, IZUMO3, AL353811.1, RMRPP5, RN7SKP120, TUSC1, LINC01241, FAM71BP1.
- chr17:18,426,861–18,551,705, 11 genes (within-gene range 0–2): KRT17P2, KRT16P1, KRT16P4, AL353997.1, AL353997.4, TNPO1P2, LGALS9C, NOS2P2, FAM106A, USP32P2, SRP68P2.
- chr18:45,034–73,545, 3 genes: AP001005.1, TUBB8B, AP001005.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,212 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:102,199,739–102,389,630, 1 gene, copy number 5: AC114485.1.
- chr3:165,122,713–198,123,232, 619 genes, copy number 5–14 (broad region; genes not listed).
- chr4:54,440,502–59,075,256, 82 genes, copy number 13–119 (broad region; genes not listed).
- chr5:58,198–45,895,970, 679 genes, copy number 6 (broad region; genes not listed).
- chr6:54,770,583–58,438,364, 42 genes, copy number 5 (within-gene range 4–5): KRASP1, RNU6-1023P, AL512363.1, FAM83B, AL049555.1, HCRTR2, GFRAL, HMGCLL1, AL590290.1, BMP5, NPM1P36, COL21A1, DHFRP6, AL031779.1, RCC2P7, DST, DST-AS1, RPL17P26, RNU6-626P, BEND6, OSTCP6, FTH1P15, MRPL30P1, KIAA1586, ZNF451, ZNF451-AS1, BAG2, RAB23, PRIM2, MIR548U, FO680682.1, AL021368.3, AL021368.1, AL021368.2, GUSBP4, AL021368.4, POM121L14P, LINC00680, AL445250.1, GAPDHP15, AL390237.1, RBBP4P4.
- chr7:45,574,140–46,343,621, 17 genes, copy number 5: ADCY1, SEPTIN7P2, GTF2IP13, RNU6-241P, CICP20, AC096582.1, AC096582.2, RNU6-326P, IGFBP1, IGFBP3, AC073115.2, AC073115.1, FTLP15, TTC4P1, ZNF619P1, AC023669.1, AC023669.2.
- chr7:93,424,486–94,669,695, 23 genes, copy number 5: CALCR, MIR653, MIR489, GNGT1, AC002075.2, MIR4652, AC002075.1, NDUFAF4P2, TFPI2, TFPI2-DT, AC002076.1, GNG11, AC006378.1, BET1, BET1-AS1, AC003092.1, AC003092.2, AC002074.1, COL1A2, RNU6-1328P, CASD1, SGCE, PEG10.
- chr7:94,907,202–97,991,169, 55 genes, copy number 5: PPP1R9A, HINT1P2, AC002429.1, PPP1R9A-AS1, RNU4-16P, PON1, AC004022.2, AC004022.1, PON3, PON2, AC005021.1, AC004012.1, ASB4, AC002451.2, AC002451.1, PDK4, DYNC1I1, AC002540.1, SLC25A13, MIR591, AC096775.1, AC084368.1, RNU6-532P, RNU6-364P, RNU7-188P, SEM1, MARK2P10, RN7SL252P, DLX6-AS1, AC004774.1, AC004774.3, DLX6, AC004774.2, DLX5, SDHAF3, HMGB3P21, AC073900.1, AP1S2P1, RN7SKP104, TAC1, ASNS, AC079781.5, AC005326.1, SNRPCP9, RPS3AP29, AC079781.1, AC079781.2, AC079781.3, OR7E7P, MIR5692A1, MIR5692C2, OR7E38P, AC004967.2, AC004967.1, OCM2.
- chr8:46,028,804–51,321,118, 74 genes, copy number 8–9 (within-gene range 3–9) (broad region; genes not listed).
- chr8:52,534,037–63,234,911, 160 genes, copy number 8–13 (broad region; genes not listed).
- chr8:137,696,724–141,195,808, 30 genes, copy number 5: AC110053.1, AC046195.1, AC046195.2, AC079015.1, FAM135B, COL22A1, AC027541.1, AC100807.1, AC100807.2, AC087354.1, AC090093.1, KCNK9, TRAPPC9, AC021744.1, C8orf17, AC040978.1, PEG13, AC107375.1, CHRAC1, AGO2, AC067931.1, AC067931.2, ERICD, PTK2, MIR151A, AC105235.1, RNA5SP278, AC100860.1, DENND3, AC040970.1.
- chr11:89,752,785–89,999,741, 27 genes, copy number 5: UBTFL2, AP003122.2, AP003122.3, AP003122.1, TRIM64DP, AP004833.2, AP004833.3, TRIM49, AP004833.1, TRIM53BP, TRIM51BP, AP005435.1, TRIM64B, AP005435.4, AP005435.2, AP005435.3, MTND1P35, TRIM49D1, TRIM49D2, AP004607.3, AP004607.9, AP004607.8, AP004607.1, TRIM64, AP004607.7, TRIM51EP, TRIM53AP.
- chr13:23,465,776–23,487,712, 1 gene, copy number 7: LINC00327.
- chr18:26,133,852–27,595,164, 31 genes, copy number 5: PSMA8, DHFRP1, NPM1P2, TAF4B, SINHCAFP1, AC121320.1, AC022069.1, RNU6-1289P, LINC01543, KCTD1, AC007996.1, AC090206.1, MIR8057, CIAPIN1P, AQP4-AS1, AC012588.1, PCAT18, U3, AC018371.1, AC018371.2, AQP4, CHST9, ATP6V1E1P2, LINC01908, AC090403.1, AC021382.1, UBA52P9, AC068408.1, RBM22P1, PA2G4P3, AC068408.2.
- chr18:49,469,803–49,837,623, 17 genes, copy number 5 (within-gene range 4–5): PRR13P4, C18orf32, RPL17-C18orf32, AC100778.2, AC100778.3, MIR1539, RPL17, SNORD58C, SNORD58A, SNORD58B, SRP72P1, LINC02837, LIPG, SMUG1P1, AC090227.3, ACAA2, AC090227.2.
- chr18:49,814,133–49,814,443, 2 genes, copy number 5 (within-gene range 4–5): SCARNA17, AC090227.1.
- chr22:15,282,557–50,801,309, 1,352 genes, copy number 5–13 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,421. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
